Gene-level copy-number profile of tumor specimen C3L-03143-01 from CPTAC case C3L-03143, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IVB; FIGO stage: Stage IVB; Age at diagnosis: 67.2 years (24,543 days).
Specimen C3L-03143-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 111b31b4-5b6a-4841-b08d-26f077908d7e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03143-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,239 have no estimate.
https://portal.gdc.cancer.gov/files/102e3d97-9bf7-41ec-9a69-d23d23441918

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 2,433; copy number 2: 31,057; copy number 3: 16,723; copy number 4: 5,665; copy number 5: 1,930; copy number 6: 246; copy number 7: 157; copy number 8: 126; copy number 9: 29; copy number 10: 7.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,064,089–181,523,001, 4 genes: LINC00290, AC019235.1, LINC02500, AC093840.1.
- chr6:118,460,772–118,710,075, 5 genes (within-gene range 0–2): CEP85L, BRD7P3, PLN, Z99496.1, SSXP10.
- chr15:21,298,233–21,325,241, 2 genes: AC068446.2, RNU6-1235P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,495 genes in 64 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:33,466,249–44,390,823, 313 genes, copy number 5–9 (broad region; genes not listed).
- chr1:46,967,679–47,180,339, 11 genes, copy number 6: CYP4A26P, CYP4A43P, CYP4A27P, CYP4A44P, CYP4X1, CYP4Z1, TUBAP9, CYP4A22-AS1, CYP4A22, MTND1P34, LINC00853.
- chr1:154,272,589–154,559,028, 18 genes, copy number 5: HAX1, AL354980.1, RNU6-239P, RNU6-121P, AL354980.2, AQP10, ATP8B2, RNU7-57P, AL162591.1, RPSAP17, IL6R-AS1, IL6R, PSMD8P1, SHE, AL162591.2, TDRD10, UBE2Q1, UBE2Q1-AS1.
- chr1:156,147,366–156,881,850, 44 genes, copy number 5: SEMA4A, AL135927.1, SLC25A44, PMF1-BGLAP, PMF1, BGLAP, PAQR6, SMG5, TMEM79, GLMP, VHLL, CCT3, TSACC, RHBG, AL139130.1, MIR9-1HG, MIR9-1, MEF2D, Y_RNA, AL365181.1, IQGAP3, TTC24, NAXE, GPATCH4, AL365181.4, HAPLN2, AL365181.2, BCAN, AL365181.3, AL590666.2, NES, AL590666.3, AL590666.4, CRABP2, AL590666.1, ISG20L2, RRNAD1, MRPL24, HDGF, PRCC, AL590666.5, SH2D2A, NTRK1, INSRR.
- chr1:197,268,204–198,937,471, 21 genes, copy number 5: CRB1, MRPS21P3, AL136322.1, DENND1B, Y_RNA, EEF1A1P32, AL365258.2, FAM204BP, AL365258.1, C1orf53, LHX9, NEK7, PRR13P1, ATP6V1G3, AL157402.1, PTPRC, AL157402.2, PEBP1P3, MIR181A1HG, MIR181B1, MIR181A1.
- chr1:205,042,937–206,464,443, 46 genes, copy number 5–7: CNTN2, TMEM81, RBBP5, AL583832.1, AC093422.2, DSTYK, AC093422.1, TMCC2, TMCC2-AS1, NUAK2, KLHDC8A, SNRPGP10, LEMD1-AS1, LEMD1, BLACAT1, MIR135B, LEMD1-DT, CDK18, RNU2-19P, MFSD4A, RNU6-418P, ELK4, AC096533.1, SLC45A3, Metazoa_SRP, NUCKS1, SNORA72, RAB29, SLC41A1, AC119673.2, PM20D1, SLC26A9, AL713965.1, RAB7B, CTSE, BX571818.1, RHEX, AC244035.3, AVPR1B, AC244035.1, AC244035.4, RPL22P4, AC244035.2, FAM72A, SRGAP2, AC244023.1.
- chr1:223,779,893–224,010,612, 8 genes, copy number 6: TP53BP2, PHBP11, ACTBP11, CICP5, GTF2IP20, RNU6-1319P, AC138393.1, AC138393.3.
- chr1:234,724,042–235,161,283, 14 genes, copy number 5 (within-gene range 3–5): LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3, LINC01348, AL732292.1, AL732292.2, TOMM20, SNORA14B, RBM34.
- chr3:49,716,829–50,100,045, 18 genes, copy number 5 (within-gene range 3–5): AMIGO3, GMPPB, IP6K1, COX6CP14, AC139451.1, CDHR4, INKA1, UBA7, MIR5193, TRAIP, CAMKV, RN7SL217P, ACTBP13, MST1R, AC105935.2, AC105935.1, MON1A, RBM6.
- chr3:52,401,008–52,579,237, 8 genes, copy number 5 (within-gene range 3–5): BAP1, PHF7, SEMA3G, TNNC1, NISCH, STAB1, NT5DC2, SMIM4.
- chr3:123,585,300–124,726,325, 12 genes, copy number 5–6 (within-gene range 4–6): MYLK-AS1, MYLK, MYLK-AS2, AC020634.2, AC020634.1, CCDC14, ROPN1, KALRN, MIR5002, RPL7P15, MIR6083, RNU6-143P.
- chr3:129,249,606–130,484,844, 41 genes, copy number 5: COPG1, MIR6826, AC137695.3, HMCES, H1-10, H1-10-AS1, NUP210P3, AC137695.1, AC137695.2, AL449212.1, RPL32P3, SNORA7B, EFCAB12, MBD4, IFT122, RHO, H1-8, PLXND1, RN7SL752P, AC023162.1, TMCC1, RNY3P13, U6, AC083799.1, TMCC1-AS1, AC083906.3, TRH, AC083906.1, AC083906.2, OR7E129P, OR7E21P, AC083906.4, ALG1L2, LINC02014, FAM86HP, LINC02021, ENPP7P3, SNRPCP8, COL6A4P2, AC093004.1, COL6A5.
- chr3:155,240,919–155,745,071, 11 genes, copy number 5 (within-gene range 4–5): LINC01487, STRIT1, AC104831.1, PABPC1P10, PLCH1, AC108729.3, AC108729.2, AC108729.1, RN7SL715P, PLCH1-AS1, PLCH1-AS2.
- chr3:155,742,142–156,037,647, 9 genes, copy number 5: AC104472.1, AC104472.2, C3orf33, AC104472.3, SLC33A1, GMPS, AC104472.5, SETP14, VN2R1P.
- chr3:168,475,198–170,418,615, 42 genes, copy number 5–6: RNU2-20P, MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2.
- chr3:172,425,850–173,336,965, 17 genes, copy number 6: BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2, ECT2, SNORA72, RNU4-4P, ATP5MC1P4, AC108667.1, SPATA16, AC068759.1.
- chr3:176,415,439–178,385,479, 22 genes, copy number 5 (within-gene range 4–5): LINC01208, RNA5SP147, LINC01209, MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P, LINC00501, ASS1P7, AC117465.1, LINC00578, RN7SKP52, AC026355.3, AC026355.1, AC026355.2, AC026355.4, LINC02015, AC007953.1, AC007953.2, RNU6-1120P, AC117453.1.
- chr3:185,282,941–185,825,042, 9 genes, copy number 5: MAP3K13, RPL4P4, TMEM41A, LIPH, SENP2, AC133473.1, IGF2BP2, IGF2BP2-AS1, MIR548AQ.
- chr5:23,443,586–24,271,863, 8 genes, copy number 6 (within-gene range 4–6): PRDM9, AC109445.1, AC108103.1, C5orf17, AC026784.1, ADH5P5, Y_RNA, AC114930.1.
- chr7:47,608,465–48,061,304, 9 genes, copy number 5: LINC01447, C7orf65, PKD1L1, LINC00525, C7orf69, AC069282.1, HUS1, SUN3, C7orf57.
- chr7:131,110,096–131,948,953, 13 genes, copy number 7 (within-gene range 3–7): MKLN1, AC009362.1, MKLN1-AS, AC008264.2, PODXL, AC008264.1, EEF1B2P6, AC093106.1, AC093106.2, NDUFB9P2, CAPZA1P4, AC009518.2, AC009518.1.
- chr7:142,626,649–143,313,061, 59 genes, copy number 5: TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBJ2-2P, TRBJ2-3, TRBJ2-4, TRBJ2-5, TRBJ2-6, TRBJ2-7, TRBC2, TRBV30, EPHB6, TRPV6, AC245427.1, TRPV5, LLCFC1, KEL, OR9A2, OR9P1P, OR6V1, OR6W1P, PIP, TAS2R39, AC073342.1, TAS2R40, AC073342.2, GSTK1, TMEM139-AS1, TMEM139, CASP2, RN7SL535P, RN7SL481P, HINT1P1.
- chr8:33,226,848–34,039,104, 21 genes, copy number 5: AC104027.1, RNU6-528P, AC067838.1, FUT10, AC091144.2, TTI2, MAK16, SNORD13, AC091144.1, SNORA70, RPL10P18, RNF122, RN7SL621P, DUSP26, AF279873.3, BUD31P1, RN7SL457P, VENTXP5, AF279873.2, AF279873.1, AF279873.4.
- chr8:70,109,782–71,228,629, 15 genes, copy number 6 (within-gene range 4–6): NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P, AC022730.1, TRAM1, LACTB2-AS1, LACTB2, RN7SL19P, XKR9, AC015687.1, Y_RNA.
- chr8:80,034,745–80,568,506, 18 genes, copy number 5 (within-gene range 4–5): TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2.
- chr8:86,180,418–86,818,558, 15 genes, copy number 6: AC084128.1, SLC7A13, AC103760.1, WWP1, RMDN1, NTAN1P2, SLC2A3P4, CPNE3, CNGB3, MIOXP1, GOLGA2P1, UBE2Q2P10, AC090572.3, AC090572.2, AC090572.1.
- chr8:93,915,734–101,492,499, 168 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:132,570,416–133,963,259, 30 genes, copy number 5: LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2.
- chr8:143,541,648–144,756,417, 96 genes, copy number 8 (broad region; genes not listed).
- chr10:16,276,871–17,237,593, 14 genes, copy number 5: LINC02654, PTER, RNU2-18P, C1QL3, AL353576.1, RSU1, AC073367.1, AL365215.1, CUBN, AC067747.1, TRDMT1, VIM-AS1, VIM, AL133415.1.
- chr13:94,960,041–96,053,482, 18 genes, copy number 5–6: LINC00557, AL139381.1, RNU6-62P, ABCC4, RNY3P8, RNY4P27, MEMO1P5, CLDN10, CLDN10-AS1, DZIP1, DNAJC3-DT, DNAJC3, MTND5P2, MTND6P18, MTCYBP3, AL138955.1, UGGT2, HMGN1P24.
- chr13:97,675,011–99,957,167, 50 genes, copy number 5–8: AL359502.1, RPL7AP61, AL356580.1, IPO5, FTLP8, FARP1, RNF113B, RN7SKP8, MIR3170, AL445223.1, AL161896.1, FARP1-AS1, STK24, AL356423.1, STK24-AS1, NUS1P4, CYCSP35, CALM2P4, RN7SL60P, SLC15A1, DOCK9, DOCK9-AS1, AL161420.1, RPL7L1P12, RNU6-83P, DOCK9-DT, RPS6P23, UBAC2-AS1, GAPDHP22, UBAC2, RN7SKP9, H2AZP3, GPR18, GPR183, MIR623, HMGB3P4, CCR12P, TM9SF2, LINC01232, AL139035.1, LINC00449, LINC01039, CFL1P8, CLYBL, MIR4306, CLYBL-AS2, CLYBL-AS1, AL137139.1, AL137139.3, AL137139.2.
- chr13:104,814,327–114,337,626, 151 genes, copy number 5–9 (broad region; genes not listed).
- chr14:18,333,726–19,714,332, 69 genes, copy number 5–8 (broad region; genes not listed).
- chr14:75,127,153–75,546,993, 13 genes, copy number 6 (within-gene range 4–6): AL049780.2, TMED10, AL691403.2, RNU4ATAC14P, AL691403.1, AF111167.1, U2, FOS, DPPA5P4, LINC01220, AF111167.2, JDP2, BATF.
- chr16:1,938,229–2,643,296, 87 genes, copy number 6 (broad region; genes not listed).
- chr16:11,668,455–11,976,643, 17 genes, copy number 5: SNN, TXNDC11, AC007613.1, ZC3H7A, Metazoa_SRP, AC010654.1, BCAR4, RSL1D1, AC007216.4, GSPT1, AC007216.3, COX6CP1, AC007216.2, AC007216.5, NPIPB2, TNFRSF17, UBL5P4.
- chr19:27,638,483–28,125,430, 15 genes, copy number 5: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1.
- chr20:25,985,210–64,327,972, 881 genes, copy number 5–9 (broad region; genes not listed).
- chr21:13,609,858–13,705,518, 7 genes, copy number 6–10: POTED, RNU6-286P, AL050303.2, GRAMD4P1, CXADRP1, AL050303.3, LONRF2P5.

Autosomal genes at a single copy (total copy number 1): 2,428. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
